Somatic mutation profile of tumor specimen MP2PRT-PATLVW-TMP1-A (aliquot MP2PRT-PATLVW-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATLVW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (970 days).
Specimen MP2PRT-PATLVW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc92fb9e-9b24-4751-802f-f744ae95c0ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATLVW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATLVW-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0888c4a-d3f2-49b0-ab53-4f318c2bb825

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ECPAS | c.3677G>A p.S1226N | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1256348279; called by muse, mutect2
- LCOR | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 100/296 reads (34%) | catalogued as COSV53718519; called by muse, mutect2, varscan2
- SPTBN4 | c.6115C>T p.R2039C | Missense Mutation (SNP) | VAF 174/461 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs577000571; called by muse, mutect2, varscan2
- SUSD4 | c.1376A>T p.N459I | Missense Mutation (SNP) | VAF 179/425 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DLC1 | c.3585C>T p.D1195= (on ENST00000276297 / NM_001348081.2; = p.D758= on NM_006094.5) | Silent (SNP) | VAF 175/415 reads (42%) | catalogued as rs752507184, COSV52298324; called by muse, mutect2, varscan2
